Somatic mutation profile of tumor specimen C3N-00437-03 (aliquot CPT0012560010) from CPTAC case C3N-00437, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 69.8 years (25,495 days).
Specimen C3N-00437-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0048d85-fc51-43d3-b727-9a286b6d7742.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00437-31 (Blood Derived Normal), aliquot CPT0012620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a08e269f-1682-4696-a3c9-0de4f52b1828

The open-access MAF lists 88 somatic variants for this specimen: 56 protein-altering or splice-affecting, 18 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 18, Intron 9, Frame Shift Del 5, 5'Flank 2, Splice Site 2, RNA 1, Nonsense Mutation 1, 5'UTR 1, 3'UTR 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS1 | c.2503G>T p.A835S | Missense Mutation (SNP) | VAF 236/666 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs775304067; called by muse, mutect2, varscan2
- ADGRB1 | c.3352G>A p.V1118M | Missense Mutation (SNP) | VAF 52/570 reads (9%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.999); catalogued as rs781741541; called by muse, mutect2
- ADH7 | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as rs1385786745; called by muse, mutect2, varscan2
- CCDC9B | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs749903593; called by muse, mutect2, varscan2
- CYP7A1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 65/560 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149291486; called by muse, mutect2, varscan2
- DVL1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 76/144 reads (53%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.616); catalogued as rs1375216646, COSV101127283; called by muse, mutect2, varscan2
- FBXO43 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 36/398 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV71053744; called by muse, mutect2
- FLG | c.2603G>C p.G868A | Missense Mutation (SNP) | VAF 62/780 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs760204561, COSV64243215; called by muse, mutect2
- GAL | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.633); catalogued as COSV55763762; called by muse, mutect2, varscan2
- GFOD1 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as rs771312460, COSV64954663; called by muse, mutect2, varscan2
- IER3 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 136/359 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1014107448, COSV52543581, COSV52544563; called by muse, mutect2, varscan2
- LAMP2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs397516741; ClinVar: likely benign; called by muse, mutect2
- LRRC4B | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 147/365 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV100975878; called by muse, mutect2, varscan2
- OR6C68 | c.734T>A p.V245E | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1007875087; called by muse, mutect2, varscan2
- RBMXL3 | c.2825G>A p.R942H | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.84); catalogued as rs868941610, COSV57762046; called by muse, mutect2, varscan2
- SMARCA2 | c.2348+1G>A p.X783_splice | Splice Site (SNP) | VAF 9/64 reads (14%) | catalogued as COSV61809852; called by muse, varscan2
- TMEM210 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.711); catalogued as rs772030467; called by muse, mutect2, varscan2
- VHL | c.419del p.L140Pfs*19 | Frame Shift Del (DEL) | VAF 141/374 reads (38%) | catalogued as CD983003, COSV56568261; called by mutect2, pindel, varscan2
- ADAMTS20 | c.5641G>A p.E1881K | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- APOB | c.10781G>T p.W3594L | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- BAP1 | c.338_350del p.S113Tfs*70 | Frame Shift Del (DEL) | VAF 92/279 reads (33%) | called by mutect2, pindel, varscan2
- CACNB1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 39/170 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- CARD6 | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CFAP251 | c.1901A>C p.N634T | Missense Mutation (SNP) | VAF 205/565 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CPSF1 | c.2248G>C p.D750H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- DBX1 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- DSC1 | c.2109_2116+11del p.X703_splice | Splice Site (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel
- FAM170B | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 142/334 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- FLG | c.10382G>C p.G3461A | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- FLG | c.6494G>C p.G2165A | Missense Mutation (SNP) | VAF 124/726 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.175); called by muse, varscan2
- IGHM | c.64A>C p.S22R | Missense Mutation (SNP) | VAF 115/228 reads (50%) | SIFT tolerated (0.23); called by muse, mutect2, varscan2
- KLHL10 | c.282dup p.E95* | Frame Shift Ins (INS) | VAF 49/272 reads (18%) | called by mutect2, pindel, varscan2
- MBLAC2 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOL12 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- OPTN | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 193/489 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- OVCH1 | c.449del p.K150Sfs*62 | Frame Shift Del (DEL) | VAF 21/155 reads (14%) | called by mutect2, pindel, varscan2
- PARP9 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PCDHGC3 | c.328T>A p.L110M | Missense Mutation (SNP) | VAF 262/442 reads (59%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PDK2 | c.1064A>T p.D355V | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PHRF1 | c.1956A>C p.R652S (on ENST00000264555 / NM_001286581.2; = p.R651S on NM_020901.4) | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIWIL1 | c.1543C>A p.L515I | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PKDREJ | c.3274G>T p.D1092Y | Missense Mutation (SNP) | VAF 83/281 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRDM10 | c.1816C>A p.H606N | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRKACA | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RCOR3 | c.653del p.P218Lfs*6 | Frame Shift Del (DEL) | VAF 144/355 reads (41%) | called by mutect2, pindel, varscan2
- RNF34 | c.1307T>G p.L436R | Missense Mutation (SNP) | VAF 138/489 reads (28%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCRN3 | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SEPSECS | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 56/212 reads (26%) | called by muse, mutect2, varscan2
- SETD2 | c.2727T>G p.D909E | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SI | c.228C>G p.N76K | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC25A53 | c.595A>T p.I199F | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- THEGL | c.1229del p.T410Ifs*13 | Frame Shift Del (DEL) | VAF 25/143 reads (17%) | called by mutect2, pindel, varscan2
- TNC | c.5613A>T p.K1871N | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TTC23 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNFX1 | c.3778C>T p.L1260F | Missense Mutation (SNP) | VAF 126/513 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZXDA | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AFF2 | c.612C>G p.P204= | Silent (SNP) | VAF 117/360 reads (33%) | catalogued as COSV60678872; called by muse, mutect2, varscan2
- AFF2 | c.948G>T p.G316= | Silent (SNP) | VAF 106/275 reads (39%) | catalogued as rs782587704; called by muse, mutect2, varscan2
- BRCA2 | c.8265A>G p.G2755= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as rs781363913; ClinVar: likely benign; called by muse, mutect2, varscan2
- C2orf81 | c.1110T>G p.S370= | Silent (SNP) | VAF 16/129 reads (12%) | called by muse, mutect2, varscan2
- CHEK2 | c.90C>A p.G30= | Silent (SNP) | VAF 86/232 reads (37%) | called by muse, mutect2, varscan2
- FAM104A | c.486C>T p.L162= | Silent (SNP) | VAF 110/483 reads (23%) | called by muse, mutect2, varscan2
- HYDIN | c.9408G>A p.L3136= | Silent (SNP) | VAF 8/35 reads (23%) | called by muse, varscan2
- IGFBP3 | c.181C>T p.L61= | Silent (SNP) | VAF 30/112 reads (27%) | called by muse, mutect2, varscan2
- MAGEL2 | c.3141G>T p.V1047= | Silent (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- MCM5 | c.510C>T p.I170= | Silent (SNP) | VAF 38/346 reads (11%) | called by muse, mutect2, varscan2
- MORC2 | c.2970G>A p.T990= (on ENST00000397641 / NM_001303256.3; = p.T928= on NM_014941.3) | Silent (SNP) | VAF 80/576 reads (14%) | catalogued as rs781327828, COSV53203448; ClinVar: likely benign; called by muse, mutect2, varscan2
- NXPE1 | c.474C>T p.D158= (on ENST00000424269; = p.D16= on NM_152315.5) | Silent (SNP) | VAF 59/188 reads (31%) | called by muse, mutect2, varscan2
- PNPLA7 | c.3810C>T p.D1270= | Silent (SNP) | VAF 68/166 reads (41%) | catalogued as rs138586605; called by muse, mutect2, varscan2
- PXDN | c.69G>A p.G23= | Silent (SNP) | VAF 92/558 reads (16%) | catalogued as rs995355920; called by muse, mutect2, varscan2
- RRP7A | c.418C>T p.L140= | Silent (SNP) | VAF 77/343 reads (22%) | called by muse, mutect2, varscan2
- SEMA4G | c.2268C>T p.I756= (on ENST00000370250; = p.I761= on NM_017893.3) | Silent (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- TFAP2D | c.745T>C p.L249= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as rs549396552; called by muse, mutect2, varscan2
- TFEC | c.312T>A p.I104= | Silent (SNP) | VAF 61/146 reads (42%) | called by muse, mutect2, varscan2
- AC092329.3 | c.-211-303G>T | Intron (SNP) | VAF 12/76 reads (16%) | called by muse, varscan2
- CHST10 | c.-104+394_-104+395del | Intron (DEL) | VAF 111/295 reads (38%) | called by mutect2, pindel, varscan2
- CNOT8 | c.311+2339G>A | Intron (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- CXCL5 | c.326+44G>C | Intron (SNP) | VAF 43/158 reads (27%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137034775 C>A | 5'Flank (SNP) | VAF 181/372 reads (49%) | catalogued as rs371943249; called by muse, mutect2, varscan2
- HTR3A | c.68-260G>A | Intron (SNP) | VAF 15/47 reads (32%) | catalogued as rs1214385401; called by muse, mutect2, varscan2
- LINC01956 | n.380G>A | RNA (SNP) | VAF 106/303 reads (35%) | catalogued as rs925586377; called by muse, mutect2, varscan2
- LY6E | chr8:143018218 C>T | 5'Flank (SNP) | VAF 351/552 reads (64%) | called by muse, mutect2, varscan2
- MDM4 | c.412-289A>C | Intron (SNP) | VAF 53/115 reads (46%) | called by muse, mutect2, varscan2
- NFX1 | c.*14C>T | 3'UTR (SNP) | VAF 72/131 reads (55%) | called by muse, mutect2, varscan2
- NKRF | c.-17+2256C>A | Intron (SNP) | VAF 30/241 reads (12%) | called by muse, mutect2, varscan2
- POLR2B | c.-18C>T | 5'UTR (SNP) | VAF 34/170 reads (20%) | called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+473G>A | Intron (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- TGM2 | c.859+109C>T | Intron (SNP) | VAF 42/190 reads (22%) | called by muse, mutect2, varscan2
